Somatic mutation profile of tumor specimen TCGA-B9-4116-01A (aliquot TCGA-B9-4116-01A-01D-1252-08) from TCGA case TCGA-B9-4116, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 75.8 years (27,692 days).
Specimen TCGA-B9-4116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72061e93-b0f1-4461-9aef-72dab7a0cc39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-4116-10A (Blood Derived Normal), aliquot TCGA-B9-4116-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1f90753-64be-480f-90fd-5baf4d4b930e

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 49, Silent 22, Frame Shift Del 8, Nonsense Mutation 5, In Frame Del 3, Splice Site 3, Frame Shift Ins 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1S | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV104423928; called by muse, mutect2, varscan2
- CDH9 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50254879, COSV50270971; called by muse, mutect2, varscan2
- CLCN6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 52/980 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs768983318; called by muse, mutect2
- EGLN1 | c.1246A>T p.K416* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV104427103; called by muse, mutect2, varscan2
- MAP7 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369036954; called by muse, mutect2, varscan2
- MED7 | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as rs1249486794; called by muse, mutect2, varscan2
- OGG1 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs144249605; called by muse, mutect2, varscan2
- SCYL1 | c.2088G>A p.W696* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99534457; called by muse, mutect2, varscan2
- SLC22A16 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.253); catalogued as COSV57927573; called by muse, mutect2, varscan2
- TRIM48 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs747964790; called by muse, mutect2, varscan2
- WASHC4 | c.472_474del p.V158del | In Frame Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1379034608; called by pindel, varscan2
- ACTR5 | c.1684G>C p.G562R | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG7 | c.257T>G p.M86R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- ANKRD7 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4E1 | c.2128T>G p.W710G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATXN2 | c.1120T>C p.W374R (on ENST00000550104; = p.W214R on NM_002973.4) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BFAR | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 174/465 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C2orf80 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CA6 | c.134del p.Q45Rfs*19 | Frame Shift Del (DEL) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- CEP250 | c.5256del p.D1753Tfs*14 | Frame Shift Del (DEL) | VAF 88/302 reads (29%) | called by mutect2, pindel, varscan2
- CLEC4D | c.121+3_121+9del p.X41_splice | Splice Site (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- COX8A | c.183C>G p.H61Q | Missense Mutation (SNP) | VAF 134/499 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DENND10 | c.502A>T p.M168L | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DOCK6 | c.4271_4290del p.L1424Pfs*92 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | called by mutect2, pindel
- EIF4H | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 125/398 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EP300 | c.5236T>A p.C1746S | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT1 | c.4711G>T p.V1571F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF3 | c.329dup p.H110Qfs*18 | Frame Shift Ins (INS) | VAF 55/158 reads (35%) | called by mutect2, varscan2
- FGF3 | c.328delinsAA p.H110Kfs*18 | Frame Shift Ins (INS) | VAF 43/180 reads (24%) | called by mutect2*, pindel, varscan2*
- FGR | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 119/209 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- GUCY2D | c.3104A>C p.Y1035S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- HSD17B14 | c.710T>G p.F237C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF1R | c.2457C>A p.N819K | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ITGA7 | c.299del p.E100Gfs*60 | Frame Shift Del (DEL) | VAF 109/361 reads (30%) | called by mutect2, pindel, varscan2
- LCLAT1 | c.932_940del p.K311_E313del | In Frame Del (DEL) | VAF 36/165 reads (22%) | called by mutect2, varscan2
- LRATD2 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LRRC4C | c.1213_1217del p.V405Qfs*2 | Frame Shift Del (DEL) | VAF 51/205 reads (25%) | called by mutect2, pindel, varscan2
- MAT2A | c.549+3_549+6del p.X183_splice | Splice Site (DEL) | VAF 13/49 reads (27%) | called by pindel, varscan2
- MFSD5 | c.656T>G p.L219R | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.286); called by mutect2, varscan2
- MRTFB | c.2572T>G p.S858A (on ENST00000571589 / NM_001365412.2; = p.S808A on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYCN | c.1234G>C p.V412L | Missense Mutation (SNP) | VAF 157/478 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- NECTIN3 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- NEPRO | c.188_190del p.D63del | In Frame Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- NOD1 | c.2584A>T p.R862W | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPIPB15 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NPY2R | c.968T>G p.L323R | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- NUP214 | c.848A>T p.H283L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.203); called by muse, mutect2
- OR7E24 | c.556T>G p.C186G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PABPC4 | c.208_210delinsTA p.D70* | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | called by pindel, varscan2*
- PBX1 | c.331A>T p.M111L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHH3 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.1411A>C p.N471H | Missense Mutation (SNP) | VAF 166/471 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.3235G>C p.A1079P | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKAG2 | c.1234-1G>A p.X412_splice | Splice Site (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- RAB11B | c.545_546del p.A182Gfs*100 | Frame Shift Del (DEL) | VAF 63/225 reads (28%) | called by mutect2, pindel, varscan2
- RGL4 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEC16A | c.2873del p.P958Lfs*9 | Frame Shift Del (DEL) | VAF 68/218 reads (31%) | called by mutect2, pindel, varscan2
- SLC16A13 | c.1042_1044dup p.I348dup | In Frame Ins (INS) | VAF 126/429 reads (29%) | called by mutect2, pindel, varscan2
- SLC25A27 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SMARCC2 | c.2759T>C p.L920P | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STPG2 | c.980A>C p.N327T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TIMM44 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBTF | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UGT2B7 | c.989A>T p.Q330L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- UPF1 | c.985A>G p.I329V | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- YBX2 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZBTB11 | c.2925A>C p.Q975H | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ZC3H18 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 40/160 reads (25%) | called by muse, mutect2, varscan2
- ZNF10 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF423 | c.1809C>A p.H603Q (on ENST00000563137 / NM_001379286.1; = p.H595Q on NM_015069.4) | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNFX1 | c.5534A>C p.H1845P | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAIAP2L1 | c.1269C>T p.T423= | Silent (SNP) | VAF 45/229 reads (20%) | catalogued as rs555687728, COSV50061692; called by muse, mutect2, varscan2
- BBS2 | c.1789C>T p.L597= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- BCL7C | c.653G>A p.*218= | Silent (SNP) | VAF 280/701 reads (40%) | catalogued as rs766166981; called by muse, mutect2, varscan2
- CECR2 | c.3663T>A p.P1221= (on ENST00000342247 / NM_001290047.2; = p.P1037= on NM_001290046.1) | Silent (SNP) | VAF 52/152 reads (34%) | called by muse, mutect2, varscan2
- CHGB | c.237A>G p.T79= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs199738388, COSV66762158; called by muse, mutect2, varscan2
- GPRC5B | c.120C>T p.D40= | Silent (SNP) | VAF 77/196 reads (39%) | called by muse, mutect2, varscan2
- IL17D | c.510C>T p.V170= | Silent (SNP) | VAF 64/182 reads (35%) | called by muse, mutect2, varscan2
- IRX3 | c.1506_*11del | Silent (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel
- MINK1 | c.3957T>G p.V1319= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- MON1A | c.1950C>T p.L650= | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- NCOR1 | c.5862T>C p.S1954= | Silent (SNP) | VAF 86/316 reads (27%) | called by muse, mutect2, varscan2
- NKX2-4 | c.1038C>A p.A346= | Silent (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- PGAM1 | c.687C>T p.P229= | Silent (SNP) | VAF 73/285 reads (26%) | called by muse, mutect2, varscan2
- PIGZ | c.648T>A p.L216= | Silent (SNP) | VAF 99/234 reads (42%) | called by muse, mutect2, varscan2
- PPFIA2 | c.3457T>C p.L1153= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- RDH8 | c.789C>A p.V263= (on ENST00000651512; = p.V243= on NM_015725.4) | Silent (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- RFC1 | c.648G>A p.E216= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1336828555; called by muse, mutect2, varscan2
- SPATA31E1 | c.2082C>T p.T694= | Silent (SNP) | VAF 66/236 reads (28%) | catalogued as rs1303730104, COSV57790270; called by muse, mutect2
- SPEM1 | c.273C>A p.V91= | Silent (SNP) | VAF 125/316 reads (40%) | called by muse, mutect2, varscan2
- TMF1 | c.1149A>G p.T383= | Silent (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- YTHDF1 | c.1500A>G p.K500= | Silent (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- ZNFX1 | c.5535C>T p.H1845= | Silent (SNP) | VAF 74/218 reads (34%) | called by muse, mutect2, varscan2
